CCDI case PBBNSZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/cbebb5a3-05a1-4f72-aa07-70e8264950a6

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.4 years (3,802 days).

Biospecimens (3 samples)
- Sample 0DFA91: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFA9A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFA9H: Tissue type: Tumor; Specimen type: Solid Tissue.
